Somatic mutation profile of tumor specimen BA2914D (aliquot aq-BA2914D) from BEATAML1.0 case 2508, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 38.6 years (14,110 days).
Specimen BA2914D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bff100fa-dbc9-466e-9c61-f58d9bafe140.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2554D (Solid Tissue Normal), aliquot aq-BA2554D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c35b08b9-1a47-46c7-8ec6-93df8134338e

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 1, Frame Shift Ins 1, 3'UTR 1, Frame Shift Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 15/78 reads (19%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by pindel, varscan2
- BRK1 | c.194A>C p.E65A | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56541948; called by muse, mutect2
- SMC3 | c.1982G>C p.R661P | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV62421429, COSV62423179; called by muse, mutect2
- ADAMTS10 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- DNAJB1 | c.238G>T p.G80C | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.057); called by muse, mutect2
- DUOX1 | c.44C>A p.A15E | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); called by muse, mutect2
- TPTE2 | c.559del p.I187Ffs*14 (on ENST00000400230 / NM_199254.2; = p.I110Ffs*14 on NM_130785.3) | Frame Shift Del (DEL) | VAF 42/118 reads (36%) | called by mutect2, pindel, varscan2
- LRRTM1 | c.195C>A p.S65= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV54445976; called by muse, mutect2, varscan2
- MIF4GD | chr17:75272076 C>G | 5'Flank (SNP) | VAF 14/28 reads (50%) | called by muse, mutect2, varscan2
- NR5A1 | c.*15C>T | 3'UTR (SNP) | VAF 6/44 reads (14%) | called by mutect2, varscan2
